CCDI case PBBUPW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/4080da48-f57d-4af4-ac23-5439d0ec22d5

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 12.8 years (4,671 days).

Biospecimens (3 samples)
- Sample 0DHKQ5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM1JA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM1KB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
